Somatic mutation profile of tumor specimen TCGA-CA-5256-01A (aliquot TCGA-CA-5256-01A-01D-1408-10) from TCGA case TCGA-CA-5256, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.2 years (19,785 days).
Specimen TCGA-CA-5256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 537c0767-87fa-445d-9fc7-0321c1ecfbe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-5256-10A (Blood Derived Normal), aliquot TCGA-CA-5256-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68a1031a-c401-4354-a69e-cc4fed8d34b5

The open-access MAF lists 87 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 22, Nonsense Mutation 7, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99289019; called by muse, mutect2, varscan2
- AGO3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99869059; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99783911; called by muse, mutect2, varscan2
- ANKRD30A | c.3811G>A p.G1271R (on ENST00000611781; = p.G1215R on NM_052997.2) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760088797, COSV100653201, COSV100654067; called by muse, mutect2, varscan2
- ANO7 | c.1400A>G p.Q467R (on ENST00000274979; = p.Q413R on NM_001370694.2) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV51468012; called by muse, mutect2, varscan2
- APC | c.896_897del p.S299Cfs*27 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs397515735; called by pindel, varscan2
- ARMC5 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs552657393, COSV99192501; called by muse, varscan2
- BEND3 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416192663, COSV64681055; called by muse, mutect2, varscan2
- BTBD7 | c.3292G>A p.G1098S | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100597558, COSV100598026; called by muse, mutect2, varscan2
- CCDC80 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 84/201 reads (42%) | catalogued as COSV99245040; called by muse, mutect2, varscan2
- CKAP5 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100371100; called by muse, mutect2, varscan2
- COL15A1 | c.2182C>A p.P728T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV66644080; called by muse, mutect2, varscan2
- DDI1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100160085; called by muse, mutect2, varscan2
- DIAPH3 | c.2889A>C p.Q963H (on ENST00000400324 / NM_001042517.2; = p.Q700H on NM_030932.3) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99933997; called by muse, mutect2, varscan2
- EML5 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100715970; called by muse, mutect2, varscan2
- EOLA1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as rs376113122, COSV63734059; called by muse, mutect2, varscan2
- FAM83C | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV65584444; called by muse, mutect2
- GREB1 | c.4717G>A p.V1573M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs200385140; called by muse, mutect2, varscan2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by muse, mutect2, varscan2
- H4-16 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100797661; called by muse, mutect2, varscan2
- HCFC1 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.747); catalogued as COSV60077160; called by muse, mutect2, varscan2
- HES1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs757882940, COSV51685571; called by muse, mutect2, varscan2
- HOXD13 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV101184310; called by muse, mutect2, varscan2
- IST1 | c.365G>T p.R122L (on ENST00000535424 / NM_001270976.1; = p.R109L on NM_014761.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61708753, COSV61711018; called by muse, mutect2, varscan2
- ITGB3 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs771443640, COSV101457645; called by muse, mutect2, varscan2
- ITIH6 | c.2540C>T p.S847F | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV54486818, COSV99513650; called by muse, mutect2, varscan2
- ITIH6 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs778196393, COSV54489223; called by muse, mutect2, varscan2
- JPH2 | c.1907A>C p.K636T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV65905542; called by muse, mutect2, varscan2
- KLHL32 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs1400307277; called by muse, mutect2
- KRTAP10-11 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV58179330; called by muse, mutect2
- LRP1B | c.3862A>G p.R1288G | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101258369, COSV101262291; called by muse, mutect2, varscan2
- LTN1 | c.3526C>T p.Q1176* | Nonsense Mutation (SNP) | VAF 55/92 reads (60%) | catalogued as COSV100798077; called by muse, mutect2, varscan2
- MAP2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs181207847, COSV99561072; called by muse, mutect2, varscan2
- MAP9 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs749611120, COSV60906381; called by muse, mutect2, varscan2
- MCM10 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs533521913, COSV66335743; called by muse, mutect2, varscan2
- MUC16 | c.3455G>A p.G1152D | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV101200530; called by muse, mutect2, varscan2
- MYO10 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs753136237, COSV101569827; called by muse, mutect2
- NHSL2 | c.1424C>T p.P475L (on ENST00000510661; = p.P841L on NM_001013627.2) | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs750179274, COSV101030230; called by muse, mutect2, varscan2
- OR13A1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs376781877; called by muse, mutect2, varscan2
- OR6C70 | c.304dup p.Y102Lfs*18 | Frame Shift Ins (INS) | VAF 22/46 reads (48%) | catalogued as rs750079585; called by mutect2, varscan2
- PACRG | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs756074503, COSV61302558; called by muse, mutect2, varscan2
- PAPLN | c.899G>A p.R300H (on ENST00000554301; = p.R273H on NM_173462.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs974467079, COSV53723029; called by muse, mutect2, varscan2
- PAXIP1 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.637); catalogued as COSV68187636; called by muse, varscan2
- PCSK4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369866068, COSV99278484; called by muse, mutect2, varscan2
- PIK3CB | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100005888; called by muse, mutect2, varscan2
- SACS | c.7154T>A p.L2385H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207554, COSV66540520; called by muse, mutect2, varscan2
- SALL1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047565580, COSV51764485, COSV51765123; called by muse, mutect2, varscan2
- SEMA3C | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775561770, COSV99543419; called by muse, mutect2, varscan2
- SHCBP1L | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs549308005, COSV62355055; called by muse, mutect2, varscan2
- SLC27A5 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.61); catalogued as COSV54022481, COSV99564501; called by muse, mutect2, varscan2
- SPDL1 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | catalogued as rs1182291963, COSV99517647; called by muse, mutect2, varscan2
- STT3A | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs779755051, COSV101205240; called by muse, mutect2, varscan2
- TBX2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs373091690; called by muse, mutect2, varscan2
- TCF7L2 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV60503242; called by muse, mutect2, varscan2
- WDR36 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs747852074, COSV101540815; called by muse, mutect2, varscan2
- XIAP | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63023769; called by muse, mutect2, varscan2
- YLPM1 | c.3409C>T p.R1137* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1271803057, COSV99460552; called by muse, mutect2, varscan2
- CASD1 | c.1626dup p.A543Sfs*33 | Frame Shift Ins (INS) | VAF 33/116 reads (28%) | called by mutect2, varscan2
- ELL | c.1616_1618del p.L539del | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- NOL8 | c.3474dup p.D1159Rfs*17 | Frame Shift Ins (INS) | VAF 47/142 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R2 | c.1187_1189del p.C396del | In Frame Del (DEL) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- PLEKHA4 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- TAB3 | c.271del p.Q91Nfs*27 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel, varscan2
- ADCY8 | c.1476C>A p.T492= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99653308; called by muse, mutect2
- ADGRE1 | c.1863C>T p.I621= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs761181614, COSV51680484; called by muse, mutect2, varscan2
- AKNA | c.4119G>A p.P1373= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs375027878; called by muse, mutect2, varscan2
- ALDH1L1 | c.2679G>C p.L893= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99857218; called by muse, mutect2, varscan2
- AWAT1 | c.372G>A p.S124= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs138134361, COSV100997223; called by muse, mutect2, varscan2
- CRB1 | c.744C>T p.C248= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs367580749; called by muse, mutect2, varscan2
- CREB3L1 | c.1476C>T p.N492= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs756003422, COSV55832071; called by muse, mutect2, varscan2
- CSPG4 | c.3204C>T p.I1068= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs530179831, COSV100413924; called by muse, mutect2, varscan2
- HYDIN | c.7470G>A p.A2490= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1798530; called by muse, mutect2, varscan2
- KRT27 | c.327C>T p.N109= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs370850502; called by muse, mutect2, varscan2
- LMNTD2 | c.444G>A p.T148= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs148766963; called by muse, mutect2, varscan2
- MEFV | c.318G>A p.A106= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs777765016, COSV54820988; called by muse, mutect2, varscan2
- MMP16 | c.1479C>T p.H493= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99689465; called by muse, mutect2
- NKX2-2 | c.462G>A p.S154= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as rs369872520, COSV65819449; called by muse, mutect2, varscan2
- POLQ | c.6837C>T p.P2279= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV99952577; called by muse, mutect2, varscan2
- RHOC | c.372C>T p.D124= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs138595121; called by muse, mutect2, varscan2
- SLC1A3 | c.1155C>T p.R385= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs371866521, COSV54319805; called by muse, mutect2, varscan2
- STOX2 | c.366G>A p.T122= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs750568684, COSV57849818; called by mutect2, varscan2
- TBC1D25 | c.660G>A p.L220= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1556985288, COSV100952190; called by muse, mutect2, varscan2
- TRAPPC11 | c.747C>T p.T249= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs540347620, COSV58214379; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBOX5 | c.924G>A p.T308= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs753507933, COSV53905279, COSV99418331; called by muse, mutect2, varscan2
- ZNF91 | c.2277A>G p.K759= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100323188; called by muse, mutect2, varscan2
- EEF1D | c.-7-2542C>T | Intron (SNP) | VAF 28/63 reads (44%) | catalogued as rs751524072, COSV100414941; called by muse, mutect2, varscan2
- SMOX | c.1531-443G>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs755372323, COSV53864702; called by muse, mutect2, varscan2
